Somatic mutation profile of tumor specimen MBCProject_5774_T2_WES (aliquot MBCProject_5774_T2_WES_1) from CMI case MBCProject_5774, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct and lobular carcinoma; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 64.8 years (23,667 days).
Specimen MBCProject_5774_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a09a0a2-6b27-4c2f-b6e1-4efb86742a73.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_5774_SALIVA (Saliva), aliquot MBCProject_5774_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e79f6a76-cd96-4142-826f-23a5939cdb4f

The open-access MAF lists 18 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 5, Frame Shift Del 2, Nonsense Mutation 2, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD36 | c.2070+1del | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | catalogued as rs765095653; called by mutect2, pindel
- DLG4 | c.925C>T p.R309* (on ENST00000399506 / NM_001321075.3; = p.R352* on NM_001365.4) | Nonsense Mutation (SNP) | VAF 4/29 reads (14%) | catalogued as COSV104407399; called by mutect2, varscan2
- NACA | c.384C>G p.I128M | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as COSV63268882, COSV63272062; called by muse, mutect2, varscan2
- SPECC1L | c.2312T>C p.I771T | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV58660233; called by muse, mutect2, varscan2
- STAB1 | c.1916G>T p.G639V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58741549; called by mutect2, varscan2
- CDH1 | c.2429_2430del p.F810Yfs*2 | Frame Shift Del (DEL) | VAF 5/35 reads (14%) | called by mutect2, pindel, varscan2
- CENPI | c.1681A>C p.I561L | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ITCH | c.1644A>G p.I548M (on ENST00000262650 / NM_001257137.3; = p.I507M on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- LAMA2 | c.9212A>G p.D3071G | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- OR13C3 | c.106C>T p.Q36* | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | called by mutect2, varscan2
- ZDBF2 | c.5320A>G p.K1774E | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- RAD51D | c.456T>G p.A152= | Silent (SNP) | VAF 11/97 reads (11%) | called by muse, mutect2, varscan2
- ZKSCAN2 | c.936T>C p.H312= | Silent (SNP) | VAF 6/28 reads (21%) | called by mutect2, varscan2
- ARHGEF10L | c.3185-173A>G | Intron (SNP) | VAF 6/26 reads (23%) | called by muse, varscan2
- EDN3 | c.53-14T>A | Intron (SNP) | VAF 7/23 reads (30%) | called by muse, mutect2, varscan2
- IQCF2 | c.18+10A>G | Intron (SNP) | VAF 6/30 reads (20%) | called by mutect2, varscan2
- NLRP2 | c.281-393A>G | Intron (SNP) | VAF 6/28 reads (21%) | catalogued as rs752108162; called by muse, varscan2
- NOS3 | c.2985-561T>C | Intron (SNP) | VAF 6/32 reads (19%) | called by muse, varscan2
